Somatic mutation profile of tumor specimen HCM-BROD-0421-C71-01B (aliquot HCM-BROD-0421-C71-01B-11D-A80U-36) from HCMI case HCM-BROD-0421-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.7 years (18,165 days).
Specimen HCM-BROD-0421-C71-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12624c52-aeb0-49d8-99ff-68d96a701bbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0421-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0421-C71-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f835f4e-8e32-4288-963f-ace516de901e

The open-access MAF lists 60 somatic variants for this specimen: 39 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 19, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX1 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1487171239, COSV57492723; called by muse, mutect2, varscan2
- CACNA1I | c.2476G>A p.V826I | Missense Mutation (SNP) | VAF 231/387 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.5); catalogued as rs1278074840, COSV60802941; called by muse, mutect2, varscan2
- DGKD | c.1491C>A p.H497Q (on ENST00000264057 / NM_152879.3; = p.H453Q on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs201074042; called by muse, mutect2, varscan2
- KSR2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 91/584 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs775572595, COSV60370056; called by muse, mutect2, varscan2
- NLRP4 | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 116/445 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.814); catalogued as rs778909548, COSV100015860; called by muse, varscan2
- OR4Q2 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1169457996; called by muse, mutect2, varscan2
- PDS5B | c.3851C>T p.P1284L | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as rs1308227017, COSV100220469, COSV59737349; called by muse, mutect2, varscan2
- PLA2G4F | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs769710297; called by muse, mutect2, varscan2
- PLEKHN1 | c.1703G>A p.G568D (on ENST00000379409; = p.G516D on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as COSV58021791; called by muse, mutect2, varscan2
- PLXND1 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 39/359 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.702); catalogued as rs1418833570; called by muse, mutect2, varscan2
- SPACA7 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 100/391 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs777305307; called by muse, mutect2, varscan2
- SSTR5 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 166/426 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149886925; called by muse, mutect2, varscan2
- TTN | c.10131G>T p.W3377C (on ENST00000591111; = p.W3331C on NM_003319.4) | Missense Mutation (SNP) | VAF 56/165 reads (34%) | PolyPhen probably damaging (0.999); catalogued as COSV100616273; called by muse, mutect2, varscan2
- UBE2Q1 | c.704del p.K235Rfs*8 | Frame Shift Del (DEL) | VAF 87/402 reads (22%) | catalogued as COSV52724218; called by mutect2, pindel, varscan2
- ZNF598 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 64/296 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs761237206; called by muse, mutect2, varscan2
- ZSCAN5B | c.1375C>T p.R459C | Missense Mutation (SNP) | VAF 58/555 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs764485473, COSV61999615; called by muse, mutect2
- ATP6V0D1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 107/292 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRTAC1 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 47/387 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTLA4 | c.130G>T p.A44S | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DLL3 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 150/643 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.288); called by muse, mutect2
- FCRL4 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 47/279 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- IHH | c.709A>T p.S237C | Missense Mutation (SNP) | VAF 185/456 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- INPP5B | c.1073C>T p.S358F (on ENST00000373023; = p.S278F on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, varscan2
- LILRB2 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 33/385 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.244); called by muse, mutect2
- ME2 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MIA3 | c.1970G>T p.W657L | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ODF2 | c.209dup p.G71Wfs*37 (on ENST00000434106 / NM_153433.2; = p.G115Wfs*37 on NM_153432.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 41/449 reads (9%) | called by mutect2, pindel
- OTOP2 | c.1355A>T p.D452V | Missense Mutation (SNP) | VAF 69/655 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PAEP | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PCSK5 | c.1831A>T p.K611* | Nonsense Mutation (SNP) | VAF 56/385 reads (15%) | called by muse, mutect2, varscan2
- PDGFRA | c.925G>T p.V309F | Missense Mutation (SNP) | VAF 783/1030 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PNPLA5 | c.221T>G p.M74R | Missense Mutation (SNP) | VAF 89/402 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- RBM42 | c.944C>A p.P315H | Missense Mutation (SNP) | VAF 86/902 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.75); called by muse, mutect2
- RTTN | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- SUGP2 | c.329A>T p.D110V | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TRPC7 | c.2419+1G>T p.X807_splice | Splice Site (SNP) | VAF 157/220 reads (71%) | called by muse, mutect2, varscan2
- TSLP | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 74/228 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZNF654 | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 30/361 reads (8%) | called by muse, mutect2
- ZNF831 | c.3776A>G p.H1259R | Missense Mutation (SNP) | VAF 81/293 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ADGRE1 | c.1959C>T p.L653= | Silent (SNP) | VAF 73/275 reads (27%) | catalogued as rs1460101498, COSV99165741; called by muse, mutect2, varscan2
- ADRB2 | c.822G>A p.T274= | Silent (SNP) | VAF 238/313 reads (76%) | catalogued as rs780458948; called by muse, mutect2, varscan2
- ALDH8A1 | c.387G>A p.T129= | Silent (SNP) | VAF 101/354 reads (29%) | catalogued as rs77178086, COSV55640193; called by muse, mutect2, varscan2
- DOP1B | c.4461C>T p.Y1487= | Silent (SNP) | VAF 77/294 reads (26%) | catalogued as rs755240356; called by muse, mutect2, varscan2
- DSEL | c.3402G>C p.L1134= | Silent (SNP) | VAF 131/364 reads (36%) | catalogued as COSV100025185; called by muse, mutect2, varscan2
- FAM47A | c.1674G>A p.P558= | Silent (SNP) | VAF 130/301 reads (43%) | catalogued as rs372486528, COSV60493816, COSV60495716; called by muse, mutect2, varscan2
- FOXA3 | c.828C>T p.P276= | Silent (SNP) | VAF 75/577 reads (13%) | catalogued as rs772799849; called by muse, mutect2, varscan2
- FPR1 | c.378C>T p.C126= | Silent (SNP) | VAF 42/411 reads (10%) | catalogued as rs776424230, CM995226, COSV59053255; called by muse, varscan2
- GBP4 | c.795C>T p.D265= | Silent (SNP) | VAF 80/232 reads (34%) | catalogued as rs539360281; called by muse, mutect2, varscan2
- GRK1 | c.1587C>T p.G529= | Silent (SNP) | VAF 59/368 reads (16%) | catalogued as rs553489781; called by muse, mutect2, varscan2
- LILRA1 | c.438C>G p.V146= | Silent (SNP) | VAF 72/603 reads (12%) | catalogued as rs1292548651, COSV99251865; called by muse, mutect2, varscan2
- MYH11 | c.267C>T p.D89= | Silent (SNP) | VAF 82/435 reads (19%) | called by muse, mutect2, varscan2
- MYO18B | c.3441G>A p.E1147= | Silent (SNP) | VAF 72/655 reads (11%) | called by muse, mutect2, varscan2
- RIPPLY1 | c.39T>C p.V13= | Silent (SNP) | VAF 61/316 reads (19%) | called by muse, mutect2, varscan2
- RYBP | c.495A>G p.E165= | Silent (SNP) | VAF 86/321 reads (27%) | called by muse, mutect2, varscan2
- SLC25A25 | c.549G>A p.T183= | Silent (SNP) | VAF 71/738 reads (10%) | catalogued as rs772842561; called by muse, mutect2
- ST14 | c.642C>T p.C214= | Silent (SNP) | VAF 39/376 reads (10%) | called by muse, mutect2, varscan2
- TPSD1 | c.291G>T p.L97= | Silent (SNP) | VAF 163/505 reads (32%) | called by muse, mutect2, varscan2
- UMOD | c.498C>T p.D166= | Silent (SNP) | VAF 71/425 reads (17%) | catalogued as rs1404722955; called by muse, mutect2, varscan2
- BIRC3 | c.*325T>C | 3'UTR (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
- SLC5A10 | c.983-43C>T | Intron (SNP) | VAF 66/255 reads (26%) | catalogued as COSV100525351; called by muse, mutect2, varscan2
